Gene-level copy-number profile of tumor specimen ALCH-B3GP-TTP1-A from ALCHEMIST case ALCH-B3GP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.9 years (24,799 days).
Specimen ALCH-B3GP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c5db1c7-11cf-4a81-b0ab-51986ef74aff.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3GP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,747 have no estimate.
https://portal.gdc.cancer.gov/files/359dd4ca-776c-45aa-85d3-017e512c2025

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 112; copy number 1: 19,466; copy number 2: 34,996; copy number 3: 3,220; copy number 4: 1,045; copy number 5: 20; copy number 6: 2; copy number 7: 3; copy number 8: 3; copy number 9: 1; copy number 10: 4; copy number 11: 1; copy number 19: 3.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 56 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:10,120,698–10,211,725, 3 genes (within-gene range 0–2): RRM2, AC007240.1, MIR4261.
- chr2:10,767,875–10,770,058, 1 gene (within-gene range 0–1): AC092687.3.
- chr2:23,996,795–24,063,321, 4 genes (within-gene range 0–1): RN7SL610P, MFSD2B, WDCP, RNU6-370P.
- chr2:25,160,853–25,209,202, 2 genes: POMC, LINC01381.
- chr2:27,325,849–27,357,034, 2 genes (within-gene range 0–2): GTF3C2, GTF3C2-AS1.
- chr2:27,381,195–27,489,805, 7 genes: PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P.
- chr3:9,866,711–9,880,255, 1 gene: CIDEC.
- chr3:10,293,131–10,330,285, 2 genes (within-gene range 0–1): SEC13, MIR378B.
- chr3:46,835,111–46,903,799, 2 genes: MYL3, PTH1R.
- chr3:47,495,640–47,513,712, 2 genes: ELP6, BOLA2P2.
- chr3:47,802,909–47,850,195, 3 genes (within-gene range 0–1): DHX30, AC026318.1, MIR1226.
- chr3:49,412,206–49,429,326, 4 genes (within-gene range 0–1): TCTA, AC104452.1, AMT, NICN1.
- chr3:50,292,831–50,299,416, 2 genes (within-gene range 0–2): HYAL3, NAA80.
- chr3:51,385,291–51,500,002, 3 genes: MANF, RBM15B, DCAF1.
- chr3:75,384,059–75,538,029, 7 genes (within-gene range 0–1): AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2.
- chr5:126,600,925–126,636,284, 3 genes: PHAX, AC099513.1, TEX43.
- chr7:73,593,194–73,624,543, 2 genes: MLXIPL, AC005089.1.
- chr7:131,661,952–131,665,858, 2 genes: EEF1B2P6, AC093106.1.
- chr7:152,590,641–152,676,141, 5 genes: AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2.
- chr8:8,095,946–8,116,949, 2 genes: RPS3AP31, SNRPCP17.
- chr8:30,678,066–30,767,006, 3 genes: GSR, UBXN8, HIKESHIP3.
- chr11:70,646,165–70,647,562, 1 gene (within-gene range 0–1): SHANK2-AS2.
- chr11:70,872,270–70,872,368, 1 gene (within-gene range 0–1): MIR3664.
- chr11:71,473,503–71,473,568, 1 gene (within-gene range 0–1): MIR6754.
- chr12:109,277,978–109,309,284, 1 gene: FOXN4.
- chr12:109,880,676–109,888,467, 1 gene: AC007834.1.
- chr12:111,369,261–111,403,310, 2 genes: LINC02356, HSPA8P14.
- chr12:111,839,764–111,842,902, 1 gene (within-gene range 0–1): MAPKAPK5-AS1.
- chr12:113,291,523–113,291,608, 1 gene (within-gene range 0–1): MIR6762.
- chr12:120,341,330–120,369,164, 1 gene: MSI1.
- chr12:120,443,964–120,446,384, 1 gene (within-gene range 0–2): TRIAP1.
- chr12:120,914,400–120,917,236, 2 genes: CLIC1P1, RPL12P33.
- chr12:123,762,188–123,972,831, 9 genes (within-gene range 0–2): DNAH10, CCDC92, DNAH10OS, AC068790.7, AC068790.4, AC068790.3, AC068790.2, AC068790.5, AC068790.6.
- chr12:131,022,769–131,028,060, 2 genes (within-gene range 0–1): AC078925.2, AC078925.3.
- chr16:710,746–711,277, 1 gene (within-gene range 0–2): Z97653.1.
- chr16:1,329,078–1,329,777, 1 gene: RPS20P2.
- chr16:46,469,341–46,569,097, 2 genes: ANKRD26P1, RNU6-845P.
- chr20:59,352,195–59,364,773, 2 genes: AL035250.1, AL035250.2.
- chr20:60,308,474–60,414,872, 2 genes (within-gene range 0–1): MIR646, MTCO2P1.
- chr21:8,680,538–8,701,562, 2 genes: CR381572.2, CR381572.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 37 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,629,755–87,629,834, 1 gene, copy number 6: MIR4435-1.
- chr3:190,305,707–190,322,446, 1 gene, copy number 5: CLDN1.
- chr3:194,562,978–194,564,001, 1 gene, copy number 5: RPL23AP93.
- chr6:32,840,717–32,859,851, 4 genes, copy number 5: PSMB8, PSMB8-AS1, PSMB9, TAP1.
- chr6:36,594,353–36,605,600, 1 gene, copy number 5: SRSF3.
- chr8:40,104,169–40,107,935, 1 gene, copy number 5: AC087518.1.
- chr8:42,338,454–42,405,937, 4 genes, copy number 5: POLB, RPL5P23, DKK4, VDAC3.
- chr9:62,559,839–62,711,398, 5 genes, copy number 5–19: CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, FKBP4P7.
- chr9:136,612,024–136,617,181, 1 gene, copy number 5: LINC01451.
- chr9:136,738,167–136,758,543, 5 genes, copy number 8–11: LCN10, AL355987.1, LCN6, MIR6722, LCN8.
- chr12:9,852,984–9,870,136, 2 genes, copy number 5: CLEC2B, AC091814.1.
- chr12:67,571,197–67,589,987, 1 gene, copy number 5: LINC02442.
- chr14:105,597,691–105,601,728, 1 gene, copy number 8 (within-gene range 3–8): IGHE.
- chr16:720,581–741,329, 4 genes, copy number 7–10 (within-gene range 2–10): ANTKMT, CCDC78, HAGHL, CIAO3.
- chr16:848,525–849,065, 1 gene, copy number 6: AL031008.1.
- chr16:1,273,751–1,288,837, 3 genes, copy number 5: AC120498.7, AC120498.5, TPSP2.
- chr16:1,305,547–1,309,413, 1 gene, copy number 7 (within-gene range 3–7): AC120498.9.

Autosomal genes at a single copy (total copy number 1): 16,610. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
